Somatic mutation profile of tumor specimen TCGA-QN-A5NN-01A (aliquot TCGA-QN-A5NN-01A-11D-A28R-08) from TCGA case TCGA-QN-A5NN, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 55.6 years (20,318 days).
Specimen TCGA-QN-A5NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92501488-f0ca-4386-90ea-1a18cec30505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QN-A5NN-10A (Blood Derived Normal), aliquot TCGA-QN-A5NN-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42cc7374-d8d0-43e2-ab18-13fcb5b954a8

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 19, In Frame Del 5, Nonsense Mutation 2, Splice Region 1, Intron 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1397_1408del p.L466_E469del (on ENST00000521381 / NM_181523.3; = p.L196_E199del on NM_181504.4) | In Frame Del (DEL) | VAF 20/44 reads (45%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 37/43 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1483A>G p.M495V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs777074835, COSV60694213; called by muse, mutect2, varscan2
- AOC1 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368330728; called by muse, mutect2, varscan2
- ARL15 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 27/42 reads (64%) | catalogued as rs747993020; called by muse, mutect2, varscan2
- ATF5 | c.568_570del p.S190del | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs749285908; called by mutect2, pindel, varscan2
- CDH10 | c.443T>G p.I148S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52574372; called by muse, mutect2, varscan2
- CDHR1 | c.1702G>T p.D568Y | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1367145565; called by muse, mutect2, varscan2
- CELSR2 | c.3790C>T p.R1264W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781423840, COSV99603367; called by muse, mutect2, varscan2
- CHD5 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as rs761147748, COSV52407127; called by muse, mutect2, varscan2
- CLCN2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs758247450, COSV99658487; called by muse, mutect2, varscan2
- COL11A1 | c.4796C>T p.T1599I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs751745544; called by muse, mutect2, varscan2
- CRISP1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs139194307; called by muse, mutect2, varscan2
- DLGAP2 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs776882325; called by muse, mutect2, varscan2
- DNAH1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs188467919; called by muse, mutect2, varscan2
- ECSIT | c.321T>G p.I107M | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV52939012; called by muse, mutect2, varscan2
- FRRS1 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1230659081, COSV54922019; called by muse, mutect2, varscan2
- HLA-DQA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs767929297, COSV58238385; called by muse, mutect2, varscan2
- KCNK9 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs762082844, COSV57281048; called by muse, mutect2, varscan2
- LAMA5 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs375094493, COSV53373879; called by muse, mutect2, varscan2
- LRRCC1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs756594316, COSV64482619; called by muse, mutect2, varscan2
- MAP3K19 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs199756836, COSV59638570, COSV59643584; called by muse, mutect2, varscan2
- MMEL1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs548411329, COSV56518059; called by muse, mutect2, varscan2
- MMP1 | c.1242G>C p.M414I | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59509759; called by muse, mutect2, varscan2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 45/58 reads (78%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2, varscan2
- NFATC1 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs773206226, COSV53702662; called by muse, mutect2, varscan2
- OR5I1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56887241; called by muse, mutect2, varscan2
- PCDHGA2 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as COSV53977461; called by muse, mutect2, varscan2
- PGBD1 | c.716G>C p.R239P | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52551951; called by muse, mutect2, varscan2
- PRKCG | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.608); catalogued as rs770722155, COSV54733446; called by muse, mutect2, varscan2
- PROSER1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs773038908, COSV99052085; called by muse, mutect2, varscan2
- SRGAP2 | c.705T>C p.R235= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as rs2919105; called by muse, varscan2
- ZNF862 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs758487315, COSV56222594; called by muse, mutect2, varscan2
- ANKRD11 | c.1222_1233del p.S408_S411del | In Frame Del (DEL) | VAF 25/54 reads (46%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.1375A>T p.I459F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CCDC22 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CTSZ | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHB2 | c.1844A>G p.E615G (on ENST00000400191 / NM_001309193.2; = p.E616G on NM_004442.7) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GP2 | c.868-2A>G p.X290_splice (on ENST00000381362 / NM_001007240.3; = p.X287_splice on NM_001502.4) | Splice Site (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- KIF14 | c.4810_4812del p.E1604del | In Frame Del (DEL) | VAF 11/39 reads (28%) | called by pindel, varscan2
- LARP4 | c.726C>G p.F242L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTBP | c.2715A>G p.*905Wext*31 | Nonstop Mutation (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- NEFM | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR14I1 | c.675A>C p.R225S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR4D2 | c.321G>T p.L107F | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PHKA2 | c.2174C>G p.A725G | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.2430G>C p.K810N (on ENST00000322810 / NM_201380.4; = p.K700N on NM_000445.5) | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RERE | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATS2 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- STMN4 | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SULT1A1 | c.412T>A p.S138T | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TARBP1 | c.3812C>G p.A1271G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TKFC | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMCO5A | c.236A>C p.Q79P | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- VPS16 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- WFS1 | c.2635T>C p.F879L | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB7B | c.175_177del p.F59del (on ENST00000292176; = p.F93del on NM_001252406.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 205/255 reads (80%) | called by mutect2, pindel, varscan2
- ABCB5 | c.456C>T p.I152= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs548933985, COSV51719988; called by mutect2, varscan2
- AKR1C3 | c.405A>G p.G135= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- CARD11 | c.2163C>T p.G721= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1438709962, COSV62756081; called by muse, mutect2, varscan2
- CFAP251 | c.675G>T p.R225= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- COL14A1 | c.1998T>A p.T666= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- DCHS1 | c.9366C>A p.G3122= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- DOC2A | c.159C>T p.P53= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs533248931, COSV58751252; called by muse, mutect2, varscan2
- FCHO2 | c.1470T>G p.P490= | Silent (SNP) | VAF 40/66 reads (61%) | called by muse, mutect2, varscan2
- GPR39 | c.138G>A p.L46= | Silent (SNP) | VAF 61/72 reads (85%) | catalogued as rs1365489175; called by muse, mutect2, varscan2
- OMP | c.42G>A p.P14= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs376088397; called by muse, mutect2, varscan2
- OR11H6 | c.168A>G p.T56= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs1271795016; called by muse, mutect2, varscan2
- PARP9 | c.2556T>A p.P852= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- PKD2L1 | c.1518T>C p.F506= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs749798302, COSV58395318; called by mutect2, varscan2
- RNF121 | c.288A>C p.T96= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- ROS1 | c.2865A>T p.S955= | Silent (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2, varscan2
- SND1 | c.2052C>T p.P684= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs929084701, COSV100690331, COSV61249185; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRO | c.1920C>T p.R640= | Silent (SNP) | VAF 39/45 reads (87%) | catalogued as rs756724040, COSV51504060; called by muse, mutect2, varscan2
- WDR72 | c.1797A>G p.R599= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as rs1474808374; called by muse, mutect2, varscan2
- YLPM1 | c.3354C>T p.G1118= | Silent (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- FBLN2 | c.2155+2084G>A | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
